Somatic mutation profile of tumor specimen ALCH-B1RR-TTP1-A (aliquot ALCH-B1RR-TTP1-A-2-0-D-A76N-36) from ALCHEMIST case ALCH-B1RR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.6 years (24,328 days).
Specimen ALCH-B1RR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9078ca17-8db3-4f97-8a07-994d78f72b0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1RR-NB1-A (Blood Derived Normal), aliquot ALCH-B1RR-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78645114-86db-4451-affa-bf6fc89dc667

The open-access MAF lists 338 somatic variants for this specimen: 222 protein-altering or splice-affecting, 77 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 193, Silent 77, Intron 19, Nonsense Mutation 17, RNA 7, 3'UTR 6, Splice Site 6, 5'UTR 3, Frame Shift Del 3, 5'Flank 2, 3'Flank 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 68/534 reads (13%) | catalogued as rs786202918, CM981673, COSV100910801, COSV64288504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 296/617 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM30 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 128/392 reads (33%) | catalogued as COSV65561711; called by muse, mutect2, varscan2
- ADAMDEC1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 153/605 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56474749; called by muse, mutect2, varscan2
- ALDH1L2 | c.1610C>A p.T537N | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV51560363; called by muse, mutect2
- AP002748.5 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 74/920 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs1263024783; called by muse, mutect2
- ARHGEF15 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV62725985; called by muse, mutect2, varscan2
- ATR | c.6568C>T p.R2190C | Missense Mutation (SNP) | VAF 12/406 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs866304619, COSV63390464; called by muse, mutect2
- B4GALNT1 | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57543461; called by muse, varscan2
- BNC1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV61757455; called by muse, mutect2, varscan2
- BRINP1 | c.1889G>T p.R630L | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.49); catalogued as COSV56292314; called by muse, mutect2, varscan2
- BRWD3 | c.1010G>T p.S337I | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV64747829; called by muse, mutect2, varscan2
- C2CD3 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV58089448; called by muse, mutect2, varscan2
- CLIP3 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 32/842 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1188306227, COSV99431250; called by muse, mutect2
- CLSTN2 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 877/1706 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV71718074, COSV71720623; called by muse, mutect2, varscan2
- CNKSR2 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 106/344 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV54256468, COSV99666978; called by muse, mutect2, varscan2
- CRYBB3 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 226/1036 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs1005798300; called by muse, mutect2, varscan2
- CYP4A11 | c.1395C>A p.N465K | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as COSV60226117; called by muse, mutect2, varscan2
- DLG3 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 154/582 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs866252799; called by muse, mutect2, varscan2
- DMP1 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.638); catalogued as COSV56819926; called by muse, mutect2
- EGR4 | c.1271C>T p.A424V (on ENST00000545030; = p.A321V on NM_001965.4) | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs753449284; called by muse, varscan2
- ELL2 | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 113/311 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52982931; called by muse, mutect2, varscan2
- F2RL2 | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV56971884; called by muse, mutect2, varscan2
- FAT3 | c.2183C>G p.S728C | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV53075010; called by muse, mutect2, varscan2
- FAT3 | c.2392C>T p.L798F | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1388991643; called by muse, mutect2
- FLG | c.9274G>C p.E3092Q | Missense Mutation (SNP) | VAF 268/714 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as COSV64242161; called by muse, mutect2, varscan2
- GP5 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 59/721 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1365823620, COSV99757021; called by muse, mutect2
- GPATCH1 | c.1389G>C p.R463S | Missense Mutation (SNP) | VAF 33/649 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs1276732023, COSV50111020, COSV50111767, COSV50112587; called by muse, mutect2
- GRM3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 52/792 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.216); catalogued as COSV64466918; called by muse, mutect2
- HHLA1 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 25/351 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs370647767; called by muse, mutect2
- HSH2D | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 155/318 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV53740689; called by muse, mutect2, varscan2
- HSPA4 | c.1854G>T p.K618N | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59182826; called by muse, varscan2
- ITIH5 | c.2227A>T p.T743S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.615); catalogued as COSV53668056; called by muse, mutect2, varscan2
- ITM2A | c.704-2A>G p.X235_splice | Splice Site (SNP) | VAF 24/107 reads (22%) | catalogued as COSV100964436; called by muse, mutect2, varscan2
- KANK4 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1317053254, COSV62986141; called by muse, mutect2
- KEAP1 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV50278110; called by muse, mutect2, varscan2
- LRRTM4 | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69140802; called by muse, mutect2, varscan2
- MAGEB4 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 57/427 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as rs766167581, COSV64396910, COSV64397715; called by muse, mutect2, varscan2
- MAGEC1 | c.3123G>T p.R1041S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV53582046; called by muse, mutect2, varscan2
- OR5J2 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 236/761 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56621172; called by muse, mutect2, varscan2
- OR5W2 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1418844330; called by muse, mutect2, varscan2
- PDE4DIP | c.4397G>C p.R1466T | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100517545; called by muse, mutect2
- PHLDB2 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 50/1332 reads (4%) | catalogued as COSV67311920; called by muse, mutect2
- RB1 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 122/374 reads (33%) | catalogued as CM146443, COSV57294196, COSV57295658; called by muse, mutect2, varscan2
- RHCG | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs756228138, COSV99174070; called by muse, mutect2, varscan2
- SHCBP1L | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 111/330 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs200451412, COSV100841014, COSV62355835; called by muse, mutect2, varscan2
- SHISAL2B | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV66620247; called by muse, mutect2, varscan2
- SI | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52272025; called by muse, mutect2, varscan2
- SKIV2L | c.3622C>T p.R1208C | Missense Mutation (SNP) | VAF 23/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs144418335, COSV61714329; called by muse, mutect2
- SSH3 | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 133/377 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.072); catalogued as COSV100354599, COSV57383865; called by muse, mutect2, varscan2
- STUB1 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 53/381 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567282437, COSV50208612; called by muse, mutect2, varscan2
- TAT | c.482A>C p.N161T | Missense Mutation (SNP) | VAF 227/571 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99054536; called by muse, mutect2, varscan2
- TBC1D8B | c.2050G>T p.A684S | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); catalogued as COSV99344754; called by muse, mutect2, varscan2
- TMEM200A | c.1207G>T p.G403C | Missense Mutation (SNP) | VAF 186/461 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.725); catalogued as COSV51657302; called by muse, mutect2, varscan2
- UNC5D | c.696G>T p.M232I | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54802964; called by muse, mutect2, varscan2
- USP26 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100896550; called by muse, mutect2, varscan2
- USP35 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV71573284; called by muse, mutect2, varscan2
- ZBBX | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 169/418 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs767537003, COSV56786670; called by muse, mutect2, varscan2
- ZFHX4 | c.8780C>A p.P2927Q | Missense Mutation (SNP) | VAF 97/398 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV50672287, COSV50678044; called by muse, mutect2, varscan2
- ZNF567 | c.923C>A p.P308H (on ENST00000536254 / NM_001322913.1; = p.P277H on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as rs781418271; called by muse, mutect2
- ADCYAP1R1 | c.326C>G p.S109* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- ADGRB1 | c.1235G>A p.W412* | Nonsense Mutation (SNP) | VAF 90/294 reads (31%) | called by muse, mutect2, varscan2
- ADRA1B | c.1304C>G p.A435G | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHCTF1 | c.5152G>C p.E1718Q (on ENST00000366508; = p.E1692Q on NM_015446.5) | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- AOAH | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 69/356 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ARFIP1 | c.1093G>C p.D365H (on ENST00000353617 / NM_001287432.1; = p.D333H on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/273 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ARSL | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 140/877 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ASB17 | c.237C>G p.Y79* | Nonsense Mutation (SNP) | VAF 39/142 reads (27%) | called by muse, mutect2, varscan2
- ASPDH | c.241C>T p.H81Y (on ENST00000389208 / NM_001114598.2; = p.H26Y on NM_001024656.3) | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ATAT1 | c.63C>A p.H21Q | Missense Mutation (SNP) | VAF 24/572 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2
- ATP7A | c.1730C>A p.S577Y | Missense Mutation (SNP) | VAF 57/379 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATRNL1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 22/379 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATXN7 | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.292); called by muse, mutect2
- B4GALNT1 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- BPIFC | c.1496G>A p.R499K | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); called by muse, mutect2
- BRCA2 | c.7616A>C p.Q2539P | Missense Mutation (SNP) | VAF 224/558 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C1QTNF8 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- CA2 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 66/570 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CCDC141 | c.2255C>A p.T752N | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC54 | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 110/590 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, varscan2
- CCDC87 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 28/634 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- CD53 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 263/827 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CDH19 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 199/514 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CDYL2 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 173/381 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- CEP170B | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 17/406 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- CERCAM | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CFAP54 | c.4728G>T p.M1576I | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2
- CHL1 | c.2809G>T p.G937* (on ENST00000397491 / NM_001253387.1; = p.G953* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 48/170 reads (28%) | called by muse, mutect2, varscan2
- CHL1 | c.2810G>T p.G937V (on ENST00000397491 / NM_001253387.1; = p.G953V on NM_006614.4) | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- CLCA1 | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 36/666 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLIC5 | c.664C>A p.L222M (on ENST00000185206 / NM_001370649.1; = p.L63M on NM_016929.5) | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL11A1 | c.1450G>T p.G484C | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- COL15A1 | c.3580C>A p.L1194I | Missense Mutation (SNP) | VAF 152/705 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CSF2RB | c.1414A>T p.R472* | Nonsense Mutation (SNP) | VAF 184/647 reads (28%) | called by muse, mutect2, varscan2
- CSRNP1 | c.98G>C p.C33S | Missense Mutation (SNP) | VAF 214/442 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, varscan2
- CT47B1 | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 101/685 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CTNNA2 | c.1376G>T p.C459F | Missense Mutation (SNP) | VAF 98/366 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CTTNBP2 | c.1895C>A p.A632D | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2
- DCAF8L2 | c.1528G>T p.G510W | Missense Mutation (SNP) | VAF 146/405 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCHS1 | c.7637C>A p.P2546Q | Missense Mutation (SNP) | VAF 20/558 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.066); called by muse, mutect2
- DEFB127 | c.257C>G p.T86R | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- DHX34 | c.3034G>T p.V1012L | Missense Mutation (SNP) | VAF 147/540 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- DLG3 | c.2137G>T p.A713S (on ENST00000374360 / NM_021120.4; = p.A408S on NM_020730.3) | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK4 | c.5208G>A p.R1736= | Splice Region (SNP) | VAF 60/621 reads (10%) | called by muse, mutect2
- DOCK7 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- ELP3 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 133/535 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- FBXO21 | c.1609A>G p.M537V (on ENST00000330622 / NM_033624.3; = p.M530V on NM_015002.3) | Missense Mutation (SNP) | VAF 168/504 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FEZF2 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- FLOT1 | c.1108G>C p.G370R | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FREM3 | c.3851T>A p.L1284Q | Missense Mutation (SNP) | VAF 123/262 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GADD45A | c.497G>T p.*166Lext*8 | Nonstop Mutation (SNP) | VAF 159/404 reads (39%) | called by muse, mutect2, varscan2
- GAK | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- GHRH | c.216G>T p.R72S | Missense Mutation (SNP) | VAF 417/815 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GIMAP1 | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 193/444 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GPAT2 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 217/811 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GPR119 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 135/382 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPR52 | c.584C>G p.T195R | Missense Mutation (SNP) | VAF 183/525 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- GRM1 | c.1153C>A p.L385M | Missense Mutation (SNP) | VAF 268/747 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- HSF4 | c.670A>T p.K224* | Nonsense Mutation (SNP) | VAF 418/878 reads (48%) | called by muse, mutect2, varscan2
- HTR1A | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.11); called by muse, mutect2
- IGKV1D-42 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 69/347 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- IGSF21 | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 243/596 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF22 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2
- IMPG2 | c.1009G>T p.G337C | Missense Mutation (SNP) | VAF 81/748 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IRS4 | c.1072A>T p.R358W | Missense Mutation (SNP) | VAF 154/751 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGB4 | c.4181C>T p.P1394L | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); called by muse, mutect2
- ITPRID2 | c.3722G>T p.G1241V | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KATNIP | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 295/840 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- KCNJ3 | c.869C>A p.T290N | Missense Mutation (SNP) | VAF 40/676 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2
- KIF21A | c.1411G>T p.G471* | Nonsense Mutation (SNP) | VAF 6/135 reads (4%) | called by muse, mutect2
- KIF21B | c.3886G>T p.A1296S (on ENST00000422435 / NM_001252100.2; = p.A1283S on NM_017596.4) | Missense Mutation (SNP) | VAF 96/217 reads (44%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KIF6 | c.1558C>G p.Q520E | Missense Mutation (SNP) | VAF 109/318 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LAMP2 | c.13C>A p.R5S | Missense Mutation (SNP) | VAF 108/739 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LAMP2 | c.12C>A p.F4L | Missense Mutation (SNP) | VAF 107/734 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LEPR | c.838G>C p.V280L | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LEPR | c.2266G>T p.V756F | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LGI2 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.15); called by mutect2, varscan2
- LIPN | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LONRF2 | c.577G>C p.A193P | Missense Mutation (SNP) | VAF 144/613 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LRRC56 | c.1424G>T p.R475M | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MAGEB4 | c.545T>A p.L182Q | Missense Mutation (SNP) | VAF 188/529 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- MAP3K15 | c.210C>A p.S70R | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- MICU2 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- MIGA1 | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC16 | c.11678C>T p.T3893I | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- MXRA5 | c.2770C>A p.L924M | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- MYH14 | c.1882C>T p.Q628* | Nonsense Mutation (SNP) | VAF 98/331 reads (30%) | called by muse, mutect2, varscan2
- MYLK | c.4927G>A p.D1643N | Missense Mutation (SNP) | VAF 53/1105 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- NLRP12 | c.2746del p.Q916Rfs*33 | Frame Shift Del (DEL) | VAF 217/854 reads (25%) | called by mutect2, pindel, varscan2
- NMBR | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NONO | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NSMCE3 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 119/639 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- OR4C13 | c.610A>C p.I204L | Missense Mutation (SNP) | VAF 181/613 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- OR5T3 | c.283G>C p.V95L | Missense Mutation (SNP) | VAF 124/406 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR8A1 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 83/213 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OTOG | c.7950C>G p.I2650M | Missense Mutation (SNP) | VAF 28/453 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- PCDHA6 | c.1714G>T p.G572C | Missense Mutation (SNP) | VAF 366/876 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PCLO | c.7135G>A p.G2379S | Missense Mutation (SNP) | VAF 150/566 reads (27%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDILT | c.1360C>G p.L454V | Missense Mutation (SNP) | VAF 76/490 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PDS5A | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.301); called by muse, mutect2
- PHLDB1 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 302/697 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PIGG | c.1333-28_1340del p.X445_splice (on ENST00000453061 / NM_001127178.3; = p.X437_splice on NM_017733.4) | Splice Site (DEL) | VAF 16/195 reads (8%) | called by mutect2, pindel
- PIGG | c.1598G>T p.G533V (on ENST00000453061 / NM_001127178.3; = p.G525V on NM_017733.4) | Missense Mutation (SNP) | VAF 140/1556 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- PKM | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 167/713 reads (23%) | called by muse, mutect2, varscan2
- PLEKHH1 | c.3043G>T p.G1015C | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- PNPLA8 | c.1684-2A>C p.X562_splice | Splice Site (SNP) | VAF 28/94 reads (30%) | called by muse, varscan2
- POTEC | c.1329T>A p.D443E | Missense Mutation (SNP) | VAF 66/415 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- PPP1R16B | c.507G>A p.M169I | Missense Mutation (SNP) | VAF 91/390 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- PPP1R3C | c.572del p.D191Vfs*9 | Frame Shift Del (DEL) | VAF 100/256 reads (39%) | called by mutect2, pindel, varscan2
- PPP4R3B | c.2285del p.N762Tfs*30 (on ENST00000616407 / NM_001122964.3; = p.N677Tfs*30 on NM_020463.4) | Frame Shift Del (DEL) | VAF 37/162 reads (23%) | called by mutect2, pindel
- PRAMEF20 | c.1127G>T p.C376F | Missense Mutation (SNP) | VAF 519/1227 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- PRICKLE3 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- PSMA8 | c.316G>T p.V106F | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.068); called by muse, mutect2
- RFX8 | c.439A>C p.I147L (on ENST00000646446; = p.I76L on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RLF | c.781A>C p.M261L | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, varscan2
- RLN2 | c.184G>T p.A62S (on ENST00000381627 / NM_134441.3; = p.A13S on NM_005059.3) | Missense Mutation (SNP) | VAF 159/672 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.036); called by muse, varscan2
- RPGRIP1 | c.2732C>A p.P911H | Missense Mutation (SNP) | VAF 110/307 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RPS6KA3 | c.1075C>A p.P359T | Missense Mutation (SNP) | VAF 84/584 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RYR2 | c.1082G>T p.C361F | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); called by muse, varscan2
- SEC23B | c.1449T>A p.F483L | Missense Mutation (SNP) | VAF 498/1594 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- SETD2 | c.7233C>G p.I2411M | Missense Mutation (SNP) | VAF 161/522 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- SIGLEC1 | c.3448G>T p.G1150C | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SIGLEC8 | c.1164dup p.K389Efs*32 | Frame Shift Ins (INS) | VAF 128/854 reads (15%) | called by pindel, varscan2
- SLC22A6 | c.1252+1G>A p.X418_splice | Splice Site (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
- SLC2A9 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 194/834 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); called by muse, varscan2
- SLC6A14 | c.1678G>T p.D560Y | Missense Mutation (SNP) | VAF 64/530 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, varscan2
- SLC6A17 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 84/1179 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2
- SLC8A1 | c.2483C>G p.T828S | Missense Mutation (SNP) | VAF 134/527 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLITRK1 | c.1784A>T p.N595I | Missense Mutation (SNP) | VAF 96/825 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLITRK4 | c.1796C>G p.T599R | Missense Mutation (SNP) | VAF 68/405 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SMARCA1 | c.2491G>C p.E831Q | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- SMG6 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPRED1 | c.925G>T p.V309L | Missense Mutation (SNP) | VAF 182/894 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SSBP3 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 92/502 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, varscan2
- SUFU | c.476A>T p.D159V | Missense Mutation (SNP) | VAF 47/720 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SUZ12 | c.1795-1G>T p.X599_splice | Splice Site (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- SUZ12 | c.1795C>T p.Q599* | Nonsense Mutation (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- SYNE2 | c.14613G>T p.E4871D | Missense Mutation (SNP) | VAF 198/425 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- SYNE2 | c.18371C>G p.S6124C | Missense Mutation (SNP) | VAF 119/659 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYT6 | c.1092G>T p.E364D (on ENST00000610222 / NM_001366225.1; = p.E279D on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/290 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- TBC1D23 | c.1550A>T p.D517V | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2
- TDO2 | c.978T>G p.Y326* | Nonsense Mutation (SNP) | VAF 22/501 reads (4%) | called by muse, mutect2
- TLL2 | c.1016T>A p.I339K | Missense Mutation (SNP) | VAF 146/345 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TLR8 | c.2025G>T p.M675I (on ENST00000218032 / NM_138636.5; = p.M693I on NM_016610.4) | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM132B | c.2846G>A p.G949E | Missense Mutation (SNP) | VAF 40/484 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TP53BP2 | c.832-2A>T p.X278_splice (on ENST00000343537 / NM_001031685.3; = p.X149_splice on NM_005426.2) | Splice Site (SNP) | VAF 86/268 reads (32%) | called by mutect2, varscan2
- TRANK1 | c.1447C>G p.L483V | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- TRIM15 | c.680G>T p.C227F | Missense Mutation (SNP) | VAF 170/361 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- TRIM77 | c.466A>G p.R156G | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TTN | c.53024T>C p.I17675T (on ENST00000591111; = p.I10251T on NM_003319.4) | Missense Mutation (SNP) | VAF 29/186 reads (16%) | PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TTN | c.8379G>C p.E2793D (on ENST00000591111; = p.E2747D on NM_003319.4) | Missense Mutation (SNP) | VAF 48/786 reads (6%) | PolyPhen benign (0.114); called by muse, mutect2
- TUBAL3 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 167/325 reads (51%) | called by muse, mutect2, varscan2
- TUT4 | c.3926C>G p.P1309R | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP28 | c.3178C>G p.R1060G | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- WDR62 | c.4501G>C p.E1501Q | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XIRP2 | c.4568A>T p.N1523I (on ENST00000628543; = p.N1698I on NM_152381.6) | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- XPNPEP1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZMYM3 | c.3776C>A p.A1259D | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ZNF225 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.07); called by muse, mutect2
- ZNF331 | c.1018T>C p.S340P | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- ZNF467 | c.546C>A p.H182Q | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF567 | c.1693C>T p.Q565* (on ENST00000536254 / NM_001322913.1; = p.Q534* on NM_152603.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/392 reads (5%) | called by muse, mutect2
- ABCB7 | c.867C>T p.C289= (on ENST00000373394 / NM_001271696.3; = p.C290= on NM_004299.6) | Silent (SNP) | VAF 142/519 reads (27%) | catalogued as rs769487666, COSV53719399; called by muse, mutect2, varscan2
- ACOXL | c.489G>T p.R163= | Silent (SNP) | VAF 75/449 reads (17%) | called by muse, mutect2, varscan2
- ADAM30 | c.291G>T p.G97= | Silent (SNP) | VAF 128/392 reads (33%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.1677C>A p.T559= | Silent (SNP) | VAF 73/392 reads (19%) | catalogued as COSV99720597; called by muse, mutect2, varscan2
- ASAP1 | c.714G>A p.Q238= | Silent (SNP) | VAF 14/348 reads (4%) | catalogued as COSV63047443; called by muse, mutect2
- ASPDH | c.240C>A p.I80= (on ENST00000389208 / NM_001114598.2; = p.I25= on NM_001024656.3) | Silent (SNP) | VAF 35/197 reads (18%) | called by muse, mutect2, varscan2
- ATP7A | c.3507C>T p.I1169= | Silent (SNP) | VAF 17/250 reads (7%) | called by muse, mutect2
- ATP8B4 | c.291A>T p.T97= | Silent (SNP) | VAF 60/279 reads (22%) | called by muse, mutect2, varscan2
- BGN | c.165C>T p.V55= | Silent (SNP) | VAF 50/299 reads (17%) | catalogued as rs781783459, COSV100525236; called by muse, mutect2, varscan2
- BRCA2 | c.5442G>A p.V1814= | Silent (SNP) | VAF 70/222 reads (32%) | called by muse, mutect2, varscan2
- CCDC54 | c.552C>T p.A184= | Silent (SNP) | VAF 112/606 reads (18%) | catalogued as rs896341578; called by muse, varscan2
- CD53 | c.144C>A p.P48= | Silent (SNP) | VAF 258/820 reads (31%) | called by muse, mutect2, varscan2
- CT47B1 | c.894G>C p.G298= | Silent (SNP) | VAF 294/1015 reads (29%) | called by muse, mutect2, varscan2
- CT47B1 | c.390C>A p.S130= | Silent (SNP) | VAF 100/686 reads (15%) | catalogued as COSV64891562; called by muse, mutect2, varscan2
- DNAH6 | c.4158G>T p.V1386= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as rs1409168002; called by muse, mutect2, varscan2
- DSCAM | c.813C>T p.F271= | Silent (SNP) | VAF 22/314 reads (7%) | catalogued as COSV101261426; called by muse, mutect2
- ERN2 | c.1395C>A p.T465= | Silent (SNP) | VAF 34/174 reads (20%) | catalogued as rs762360074; called by muse, mutect2, varscan2
- EXT2 | c.1134G>A p.Q378= (on ENST00000343631; = p.Q411= on NM_000401.3) | Silent (SNP) | VAF 61/806 reads (8%) | catalogued as rs1484672018, COSV59151412; called by muse, mutect2
- FABP4 | c.24C>T p.T8= | Silent (SNP) | VAF 42/202 reads (21%) | catalogued as rs1240105262, COSV99808524; called by muse, varscan2
- GCNA | c.1851C>G p.A617= | Silent (SNP) | VAF 83/733 reads (11%) | called by muse, mutect2, varscan2
- GK3P | c.1083C>T p.V361= | Silent (SNP) | VAF 181/470 reads (39%) | catalogued as rs1490801149; called by muse, mutect2, varscan2
- GPM6A | c.88C>T p.L30= | Silent (SNP) | VAF 191/568 reads (34%) | called by muse, mutect2, varscan2
- GTF2H1 | c.1539G>A p.R513= | Silent (SNP) | VAF 9/299 reads (3%) | called by muse, mutect2
- HBE1 | c.321G>C p.L107= | Silent (SNP) | VAF 16/378 reads (4%) | catalogued as COSV53079479; called by muse, mutect2
- HTR4 | c.36G>T p.P12= | Silent (SNP) | VAF 113/315 reads (36%) | called by muse, mutect2, varscan2
- IRS4 | c.1251C>A p.P417= | Silent (SNP) | VAF 175/1003 reads (17%) | called by muse, mutect2, varscan2
- ITCH | c.747A>G p.K249= (on ENST00000262650 / NM_001257137.3; = p.K208= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 335/985 reads (34%) | called by muse, mutect2, varscan2
- ITPK1 | c.771G>T p.P257= | Silent (SNP) | VAF 51/325 reads (16%) | catalogued as COSV50894496; called by muse, mutect2, varscan2
- KCNJ5 | c.1164C>T p.G388= | Silent (SNP) | VAF 58/145 reads (40%) | called by muse, mutect2, varscan2
- KIAA1210 | c.2694T>A p.T898= | Silent (SNP) | VAF 58/322 reads (18%) | called by muse, mutect2, varscan2
- LRGUK | c.636A>T p.S212= | Silent (SNP) | VAF 67/180 reads (37%) | called by muse, mutect2, varscan2
- LRP1B | c.6114A>G p.G2038= | Silent (SNP) | VAF 38/557 reads (7%) | called by muse, mutect2
- LRRC74B | c.237G>A p.G79= | Silent (SNP) | VAF 136/493 reads (28%) | called by muse, mutect2, varscan2
- LY6G5C | c.183T>A p.L61= | Silent (SNP) | VAF 276/697 reads (40%) | called by muse, mutect2, varscan2
- MAP7D3 | c.60G>A p.R20= | Silent (SNP) | VAF 120/395 reads (30%) | called by muse, mutect2, varscan2
- MFN1 | c.213A>G p.L71= | Silent (SNP) | VAF 34/241 reads (14%) | catalogued as rs543329273; called by muse, mutect2, varscan2
- MYH4 | c.1389G>A p.L463= | Silent (SNP) | VAF 73/707 reads (10%) | called by muse, mutect2, varscan2
- MYH7 | c.714C>T p.N238= | Silent (SNP) | VAF 83/1024 reads (8%) | catalogued as rs202141819, COSV62519883; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2
- NLRP12 | c.717C>T p.L239= | Silent (SNP) | VAF 88/339 reads (26%) | called by muse, mutect2, varscan2
- NOS1 | c.3303C>T p.Y1101= | Silent (SNP) | VAF 66/630 reads (10%) | called by muse, mutect2, varscan2
- NR0B1 | c.1143C>T p.L381= | Silent (SNP) | VAF 98/672 reads (15%) | catalogued as COSV66763813; called by muse, mutect2, varscan2
- NRCAM | c.3543C>A p.I1181= (on ENST00000379028 / NM_001371124.1; = p.I1060= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 173/509 reads (34%) | called by muse, mutect2, varscan2
- NRP2 | c.2253C>A p.G751= | Silent (SNP) | VAF 38/253 reads (15%) | called by muse, mutect2, varscan2
- NXPH2 | c.654C>T p.S218= | Silent (SNP) | VAF 112/877 reads (13%) | called by muse, varscan2
- OR4A16 | c.636G>T p.L212= | Silent (SNP) | VAF 24/450 reads (5%) | called by muse, mutect2
- OR4B1 | c.597C>T p.A199= | Silent (SNP) | VAF 123/393 reads (31%) | called by muse, mutect2, varscan2
- OR8U1 | c.27G>C p.A9= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV56415432; called by muse, mutect2
- OTOP2 | c.204G>A p.A68= | Silent (SNP) | VAF 50/491 reads (10%) | catalogued as rs753447052; called by muse, mutect2, varscan2
- PANX3 | c.75C>T p.L25= | Silent (SNP) | VAF 109/311 reads (35%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1452C>A p.A484= | Silent (SNP) | VAF 496/1105 reads (45%) | called by muse, mutect2, varscan2
- PRSS48 | c.399T>C p.I133= | Silent (SNP) | VAF 293/735 reads (40%) | called by muse, mutect2, varscan2
- PRSS58 | c.513C>G p.T171= | Silent (SNP) | VAF 142/650 reads (22%) | called by muse, mutect2, varscan2
- RFX5 | c.1704C>A p.I568= | Silent (SNP) | VAF 143/1267 reads (11%) | called by muse, mutect2, varscan2
- SCAPER | c.1672A>C p.R558= | Silent (SNP) | VAF 23/407 reads (6%) | called by muse, mutect2
- SERPINA10 | c.324C>A p.A108= | Silent (SNP) | VAF 113/224 reads (50%) | catalogued as COSV56229664; called by muse, mutect2, varscan2
- SH3PXD2A | c.2067C>T p.S689= (on ENST00000369774 / NM_001365079.1; = p.S661= on NM_014631.2) | Silent (SNP) | VAF 224/521 reads (43%) | catalogued as COSV60119371; called by muse, mutect2, varscan2
- SIGLEC1 | c.1158C>T p.G386= | Silent (SNP) | VAF 28/262 reads (11%) | called by muse, mutect2, varscan2
- SLC35A2 | c.39C>A p.P13= | Silent (SNP) | VAF 54/433 reads (12%) | called by muse, mutect2, varscan2
- SLC39A12 | c.1860C>A p.G620= (on ENST00000377369 / NM_001145195.2; = p.G583= on NM_152725.3) | Silent (SNP) | VAF 115/383 reads (30%) | called by muse, mutect2, varscan2
- SMC4 | c.2505G>A p.L835= | Silent (SNP) | VAF 56/288 reads (19%) | catalogued as COSV61004904; called by muse, varscan2
- SOX21 | c.12G>C p.P4= | Silent (SNP) | VAF 370/743 reads (50%) | called by muse, mutect2, varscan2
- SPDYE6 | c.621C>T p.V207= | Silent (SNP) | VAF 108/1298 reads (8%) | called by muse, mutect2, varscan2
- SSH2 | c.1437C>G p.L479= | Silent (SNP) | VAF 13/350 reads (4%) | called by muse, mutect2
- STARD8 | c.2979C>T p.N993= | Silent (SNP) | VAF 123/387 reads (32%) | called by muse, mutect2, varscan2
- SYNE2 | c.18318C>T p.I6106= | Silent (SNP) | VAF 95/542 reads (18%) | called by muse, mutect2, varscan2
- TBC1D10A | c.93C>T p.D31= | Silent (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- TENM1 | c.7029C>A p.G2343= | Silent (SNP) | VAF 46/258 reads (18%) | catalogued as COSV64448084; called by muse, mutect2, varscan2
- TMC2 | c.2623C>A p.R875= | Silent (SNP) | VAF 314/947 reads (33%) | called by muse, mutect2, varscan2
- TRIB3 | c.693C>T p.L231= | Silent (SNP) | VAF 162/1045 reads (16%) | called by muse, mutect2, varscan2
- TUBA3C | c.1086G>T p.V362= | Silent (SNP) | VAF 89/196 reads (45%) | called by muse, mutect2
- UPK1B | c.84C>A p.A28= | Silent (SNP) | VAF 417/802 reads (52%) | called by muse, mutect2, varscan2
- UTRN | c.7899G>A p.E2633= | Silent (SNP) | VAF 178/662 reads (27%) | called by muse, mutect2, varscan2
- VNN1 | c.780C>A p.V260= | Silent (SNP) | VAF 50/154 reads (32%) | called by muse, mutect2, varscan2
- WAS | c.282G>T p.R94= | Silent (SNP) | VAF 96/666 reads (14%) | called by mutect2, varscan2
- WFDC6 | c.81C>T p.G27= | Silent (SNP) | VAF 122/514 reads (24%) | catalogued as rs771117829; called by muse, mutect2, varscan2
- YIF1B | c.492C>T p.F164= (on ENST00000339413 / NM_001039673.3; = p.F149= on NM_001039671.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 204/738 reads (28%) | called by muse, mutect2, varscan2
- ZNF541 | c.963C>A p.A321= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- AC093512.2 | c.*888+14G>A | Intron (SNP) | VAF 107/954 reads (11%) | called by muse, mutect2, varscan2
- AP2A1 | c.2114+179C>A | Intron (SNP) | VAF 30/581 reads (5%) | called by muse, mutect2
- AP2A1 | c.2115-10G>C | Intron (SNP) | VAF 18/410 reads (4%) | called by muse, mutect2
- ARR3 | c.39+22G>T | Intron (SNP) | VAF 40/307 reads (13%) | catalogued as rs767593405; called by muse, mutect2, varscan2
- BAIAP2 | c.1535+450G>C | Intron (SNP) | VAF 14/352 reads (4%) | called by muse, mutect2
- C1QTNF3 | c.84+64A>T | Intron (SNP) | VAF 1037/2256 reads (46%) | called by muse, mutect2, varscan2
- C8B | c.-22C>T | 5'UTR (SNP) | VAF 200/538 reads (37%) | called by muse, mutect2, varscan2
- C8B | c.-23G>T | 5'UTR (SNP) | VAF 199/529 reads (38%) | catalogued as rs998441000; called by muse, mutect2, varscan2
- CAGE1 | c.2113-930del | Intron (DEL) | VAF 89/239 reads (37%) | called by mutect2, pindel, varscan2
- CDH23 | c.-125G>T | 5'UTR (SNP) | VAF 61/119 reads (51%) | called by muse, mutect2, varscan2
- CLYBL | c.634+79A>T | Intron (SNP) | VAF 198/560 reads (35%) | called by muse, varscan2
- CYP11B2 | c.954+225G>T | Intron (SNP) | VAF 98/324 reads (30%) | called by muse, mutect2, varscan2
- DNAH14 | c.9205+9275A>T | Intron (SNP) | VAF 30/279 reads (11%) | called by muse, mutect2, varscan2
- DNASE1L1 | chrX:154398221 G>T | 3'Flank (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- DST-AS1 | n.139+7422G>A | Intron (SNP) | VAF 44/617 reads (7%) | called by muse, mutect2
- FCRLB | c.575-171C>T | Intron (SNP) | VAF 53/350 reads (15%) | catalogued as rs1173150808; called by muse, mutect2, varscan2
- FRMD8P1 | n.328C>T | RNA (SNP) | VAF 87/576 reads (15%) | called by muse, mutect2, varscan2
- HEXA | c.1422-22G>C | Intron (SNP) | VAF 191/823 reads (23%) | called by muse, mutect2, varscan2
- ITGAV | c.2434-25G>T | Intron (SNP) | VAF 56/278 reads (20%) | called by muse, mutect2, varscan2
- KLF6 | c.*444C>T | 3'UTR (SNP) | VAF 48/644 reads (7%) | called by muse, mutect2
- LINC01619 | chr12:91993244 C>T | 5'Flank (SNP) | VAF 38/221 reads (17%) | called by muse, mutect2, varscan2
- MIR6859-4 | chr16:16919 C>A | 3'Flank (SNP) | VAF 157/1772 reads (9%) | called by muse, mutect2
- MRRFP1 | n.127G>T | RNA (SNP) | VAF 104/526 reads (20%) | called by muse, mutect2, varscan2
- MZT2B | c.319+1043C>T | Intron (SNP) | VAF 120/365 reads (33%) | catalogued as rs992168013; called by muse, mutect2, varscan2
- OR56B3P | n.49G>A | RNA (SNP) | VAF 19/240 reads (8%) | called by muse, mutect2
- PABPC1P2 | n.813G>A | RNA (SNP) | VAF 62/487 reads (13%) | catalogued as rs1226367283; called by muse, mutect2, varscan2
- PKD1P6 | n.4175C>T | RNA (SNP) | VAF 237/778 reads (30%) | catalogued as COSV100440220; called by muse, mutect2, varscan2
- POM121L9P | n.1066G>T | RNA (SNP) | VAF 211/935 reads (23%) | called by muse, mutect2, varscan2
- PRKCZ | c.334+14636G>A | Intron (SNP) | VAF 70/361 reads (19%) | called by muse, mutect2, varscan2
- RAPGEFL1 | c.521-240A>T | Intron (SNP) | VAF 40/418 reads (10%) | called by mutect2, varscan2
- RBBP7 | c.17-316G>T | Intron (SNP) | VAF 87/536 reads (16%) | catalogued as COSV66301409; called by muse, mutect2, varscan2
- RHOJ | c.498+19T>G | Intron (SNP) | VAF 147/378 reads (39%) | called by muse, mutect2, varscan2
- SYT14 | chr1:209938203 C>T | 5'Flank (SNP) | VAF 205/433 reads (47%) | called by muse, mutect2, varscan2
- TAZ | c.*643A>T | 3'UTR (SNP) | VAF 201/1070 reads (19%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*2547T>G | 3'UTR (SNP) | VAF 69/166 reads (42%) | called by muse, mutect2, varscan2
- UBBP4 | n.475C>A | RNA (SNP) | VAF 79/460 reads (17%) | catalogued as rs758491451; called by muse, mutect2, varscan2
- XIAP | c.*826C>T | 3'UTR (SNP) | VAF 19/96 reads (20%) | catalogued as rs1354249832; called by muse, mutect2, varscan2
- XIAP | c.*4254C>A | 3'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- XIAP | c.*4255C>T | 3'UTR (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
